Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92Z, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92Z-01A (Primary Tumor).

[page 1 of 3]
Patient Name.

MRN:

DOB:

Gender:M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

ICD-O-3

Thymic carcinoma NOS 858613

Site: Thymus C37.9
g 4/2/14

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: LEFT PHRENIC

2. Thymus: THYMOMA, PERICARDIUM, WEDGE RESECTION LUL, SHORT SILK
POSTERIOR WALL OF PERICARDIUM, LONG SILK LEFT UPPER POLE THYMUS

DIAGNOSIS

1. Lymph node (left phrenic)
- Negative for malignancy

2. Resection (thymus, pericardium, portion of left upper lobe of lung):
a) Invasive thymic carcinoma (WHO type C) (see Comment), with
i) Greatest dimension = 8.0 cm
ii) Invasion of lung (left upper lobe)
iii) Invasion of pericardium not identified
iv) Lung and pericardial margins of resection negative for tumor
v) Tumor extends to within 0.1 cm of soft tissue resection
margin (superior pole)
b) Residual thymic tissue with follicular hyperplasia and
involutional changes
c) Lung with marked anthracosis

COMMENT

2. Sections show a tumor composed of nests and sheets of cells with oval to spindle nuclei with mild to moderate atypia, and moderate amount of pale cytoplasm, separated by thick fibrous bands. The cells form prominent glandular and cyst-like structures. Numerous mitoses are identified. Focal necrosis and areas of hemorrhage are noted. The tumor is almost completely encapsulated and is adherent to, but not invasive of the pericardium. However, the tumor invades the adjacent lung. The tumor also appears focally to invade the capsule and extends to within 0.1 cm of a soft tissue margin of resection at the superior pole. The tumor cells stain positive for low molecular weight keratin, CK5/6, and

[page 2 of 3]
Laboratory Medicine Program
Department of Pathology

Patient Name:

MRN:

Service:

Collected:

DOB:

Visit #:

Resulted:

Gender:M

Location:

Facility:

Ordering MD:

p63, focally positive for CK20, CD5, and CD56, and negative for smooth muscle actin, calponin, CD117, chromogranin, synaptophysin, CK7, and TTF-1.

The morphology and immunohistochemical profile are consistent with a stage III malignant thymic neoplasm (invading lung), but the findings do not fit neatly into a single WHO category. Intradepartmental review of the case by several pathologists yielded a range of opinions, from invasive thymoma of various types, to thymic carcinoma. Histologically, the presence of spindled morphology could be consistent with a type A (medullary, or spindle cell type) thymoma, in which prominent glandular and cystic structures may be seen; however, the extent of invasion and high mitotic activity would be unusual for a type A thymoma. Adenoid cystic carcinoma was also a diagnostic consideration based on morphology; however, the lack of calponin, actin, and CD117 staining do not support this diagnosis.

Overall, a diagnosis of invasive thymic carcinoma (WHO type C) is favored in this case, given the high mitotic activity, extent of invasion, and presence of focal necrosis. The presence of focal CD5 staining further supports a diagnosis of thymic carcinoma.

ELECTRONICALLY VERIFIED BY:.

CLINICAL HISTORY

THYMOMA

GROSS DESCRIPTION

1. The specimen container labeled with the patient' s name and as "left phrenic lymph node", contains a lymph node measuring 0.8 x 0.5 x 0.3 cm. received in 10% buffered formalin.

1A - submitted in toto.

2. The specimen container labeled with the patient' s name and as "thymoma, pericardium, wedge resection left upper lobe, short silk posterior wall of pericardium, long silk left upper pole thymus", it contains a thymus specimen with a wedge of lung and a portion of pericardium received in 10% buffered formalin. The entire specimen measures 13.0 cm SI x 7.0 cm ML x 5.5 cm AP. The entire specimen weighs

[page 3 of 3]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

155 grams. The specimen margins are painted with silver nitrate. The portion of pericardium measures 3.5 x 2.5 x 0.2 cm. This area is overcoated with green dye. The wedge of lung measures 7.5 cm SI x 2.3 cm ML x 1.3 cm AP. The thymus itself measures 12.5 cm SI x 4.5 cm ML x 4.0 cm AP. On sectioning, there is a solid, tan tumor located on the mid aspect of the thymus. It appears to occupy 70% of the thymus. This tumor measures 8.0 x 5.5 x 4.0 cm. On sectioning, it is tan in color with a whorl-like appearance. There is a portion of tumor that appears to be cystic, hemorrhagic and necrotic measuring 2.5 x 1.5 x 1.5 cm. The rest of the apparently normal thymic tissue is tan in color and appears to be solid. Four pieces of tumor and a piece of thymic tissue are taken for tissue banking.

Representative sections are submitted as follows:

2A-2I - deep area of pericardium with tumor serially sectioned and submitted in toto.

2J - lung wedge resection margin after the stapled resection margin is removed

2K-2N - tumor in relation to lung parenchyma

2O, 2P - tumor taken at the superior pole

2Q, 2R - apparently normal thymic tissue

2S - cystic aspect of the tumor.

Status: complete

Page: 3 of 3

Source: NCI Genomic Data Commons file 96e6ba6f-3c38-43c2-b33f-8818108c751b (TCGA-XU-A92Z.BB9BF31C-53C9-47BA-B3DD-EB96FC8820CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).